Somatic mutation profile of tumor specimen C3N-02997-01 (aliquot CPT0187880023) from CPTAC case C3N-02997, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.5 years (26,837 days).
Specimen C3N-02997-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 946a8a10-b099-468c-9bfb-f76e6fcb25fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02997-31 (Blood Derived Normal), aliquot CPT0187920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88547ef7-32bf-419f-982b-9c76495b1fed

The open-access MAF lists 67 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Nonsense Mutation 4, 3'UTR 2, 5'UTR 2, RNA 2, Frame Shift Del 1, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 218/2330 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- DCC | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 62/712 reads (9%) | catalogued as rs754914260, CM145915, COSV100502237, COSV59130602; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 88/920 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 152/1704 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2
- ADAMTS17 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 137/1514 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs142108260; called by muse, mutect2
- ADAMTS2 | c.3544C>T p.R1182* | Nonsense Mutation (SNP) | VAF 110/1152 reads (10%) | catalogued as rs367553801; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP31 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 66/696 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765209939, COSV51794256; called by muse, mutect2
- CSH1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 121/1866 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs147130406; called by muse, mutect2
- CYP26A1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 58/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1197501700; called by muse, mutect2
- DCLRE1A | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 74/617 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767319245; called by muse, mutect2, varscan2
- EGR3 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 80/772 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259984282, COSV100416239; called by muse, mutect2, varscan2
- ERBB4 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 72/765 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs138433638, COSV53504288; called by muse, mutect2
- HRNR | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 74/1126 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs144722087; called by muse, mutect2
- ITIH5 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 112/970 reads (12%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.583); catalogued as rs1356540059; called by muse, mutect2, varscan2
- LRP2 | c.12187C>T p.R4063* | Nonsense Mutation (SNP) | VAF 81/828 reads (10%) | catalogued as rs762645702, COSV55561498; called by muse, mutect2, varscan2
- NSMCE3 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 55/746 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV99722365; called by muse, mutect2
- PCSK4 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 70/932 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1429456314; called by muse, mutect2
- PNMA8A | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 210/669 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs547519581, COSV58136662; called by muse, mutect2, varscan2
- RAPGEF3 | c.556G>A p.G186R (on ENST00000389212; = p.G144R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/714 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs149525116; called by muse, mutect2
- ROBO2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 96/972 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as rs745544902, COSV59911587; called by muse, mutect2
- SDR16C5 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 109/544 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749076138; called by muse, mutect2, varscan2
- SERPINA6 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 109/1108 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.208); catalogued as COSV58584388; called by muse, mutect2
- SHROOM2 | c.3299C>T p.A1100V | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs747687263, COSV66606247; called by muse, mutect2, varscan2
- SLC25A27 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 51/691 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs771239382; called by muse, mutect2
- SYDE1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1216431016; called by muse, mutect2, varscan2
- SYNDIG1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 169/1692 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs778443324, COSV100965292, COSV65237741; called by muse, mutect2
- TRIM42 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 110/1356 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs777678502, COSV53880304, COSV53886166; called by muse, mutect2
- WWC2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 77/739 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101330845; called by muse, mutect2, varscan2
- ZNF592 | c.3329A>G p.N1110S | Missense Mutation (SNP) | VAF 127/805 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs750398742; called by muse, mutect2, varscan2
- AHNAK2 | c.7448T>A p.F2483Y | Missense Mutation (SNP) | VAF 116/1689 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ANK2 | c.7357_7360del p.D2453Lfs*7 | Frame Shift Del (DEL) | VAF 49/440 reads (11%) | called by mutect2, pindel, varscan2
- CCDC18 | c.2746G>C p.E916Q (on ENST00000343253 / NM_001306076.1; = p.E917Q on NM_206886.4) | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FYB1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 92/952 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.422); called by muse, mutect2
- HSPG2 | c.4720C>T p.P1574S | Missense Mutation (SNP) | VAF 117/1792 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- IFI16 | c.1710A>C p.E570D (on ENST00000295809 / NM_001364867.2; = p.E514D on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2
- KANSL1 | c.2253dup p.D752Rfs*29 | Frame Shift Ins (INS) | VAF 31/305 reads (10%) | called by mutect2, pindel, varscan2
- REST | c.2525T>G p.L842* | Nonsense Mutation (SNP) | VAF 105/1222 reads (9%) | called by muse, mutect2
- SCRIB | c.3099G>T p.E1033D | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.2009C>A p.A670E (on ENST00000540229 / NM_001371097.1; = p.A609E on NM_001009562.4) | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2
- SNTG2 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 49/518 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STK11IP | c.2828A>G p.E943G | Missense Mutation (SNP) | VAF 86/950 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- TBC1D23 | c.1752G>T p.W584C (on ENST00000394144 / NM_001199198.3; = p.W569C on NM_018309.5) | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV4-2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 46/774 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2
- TTN | c.84099C>A p.D28033E (on ENST00000591111; = p.D20609E on NM_003319.4) | Missense Mutation (SNP) | VAF 28/340 reads (8%) | PolyPhen benign (0.031); called by muse, mutect2
- C17orf49 | c.48C>T p.G16= | Silent (SNP) | VAF 44/508 reads (9%) | called by muse, mutect2
- CELA3A | c.591C>T p.T197= | Silent (SNP) | VAF 48/526 reads (9%) | catalogued as rs200714940; called by muse, mutect2
- CSMD1 | c.8016C>T p.S2672= (on ENST00000520002; = p.S2671= on NM_033225.6) | Silent (SNP) | VAF 29/303 reads (10%) | catalogued as rs764119199, COSV100147704; called by muse, mutect2
- CYP7B1 | c.918T>C p.Y306= | Silent (SNP) | VAF 128/2132 reads (6%) | called by muse, mutect2
- HSPA12B | c.108C>T p.C36= | Silent (SNP) | VAF 40/442 reads (9%) | catalogued as rs762188692; called by muse, mutect2
- ILDR2 | c.1590C>T p.G530= | Silent (SNP) | VAF 103/1262 reads (8%) | catalogued as rs1231965694; called by muse, mutect2
- KHDC3L | c.435G>A p.T145= | Silent (SNP) | VAF 83/844 reads (10%) | catalogued as COSV64863674; called by muse, mutect2, varscan2
- KMT2D | c.7842G>A p.S2614= | Silent (SNP) | VAF 48/662 reads (7%) | catalogued as COSV99986251; called by muse, mutect2
- KRT73 | c.54C>T p.S18= | Silent (SNP) | VAF 30/324 reads (9%) | catalogued as rs74778340; called by muse, mutect2
- LRIT1 | c.477C>T p.F159= | Silent (SNP) | VAF 161/2081 reads (8%) | called by muse, mutect2
- OTX1 | c.582G>A p.P194= | Silent (SNP) | VAF 96/1031 reads (9%) | called by muse, mutect2
- RP1 | c.3360C>T p.F1120= | Silent (SNP) | VAF 53/398 reads (13%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.2499G>A p.A833= | Silent (SNP) | VAF 67/665 reads (10%) | catalogued as COSV52661816, COSV99481199; called by muse, mutect2, varscan2
- SNAPC2 | c.48C>T p.G16= | Silent (SNP) | VAF 105/1378 reads (8%) | catalogued as rs753989260; called by muse, mutect2
- WDR90 | c.3300G>A p.P1100= | Silent (SNP) | VAF 41/564 reads (7%) | catalogued as rs375330337, COSV53473930; called by muse, mutect2
- AMDHD2 | c.*1041G>A | 3'UTR (SNP) | VAF 46/524 reads (9%) | catalogued as rs1247076616; called by muse, mutect2
- NAMPTP1 | n.1030G>A | RNA (SNP) | VAF 89/842 reads (11%) | called by muse, mutect2, varscan2
- SP8 | c.-151G>C | 5'UTR (SNP) | VAF 66/1150 reads (6%) | called by muse, mutect2
- STMP1 | chr7:135660438 C>G | 5'Flank (SNP) | VAF 46/716 reads (6%) | called by muse, mutect2
- Y_RNA | chr7:75511056 C>T | 3'Flank (SNP) | VAF 145/1822 reads (8%) | called by muse, mutect2
- ZNF137P | n.1660C>G | RNA (SNP) | VAF 66/698 reads (9%) | called by muse, mutect2
- ZNF688 | c.-618T>C | 5'UTR (SNP) | VAF 25/227 reads (11%) | catalogued as rs1189436571; called by muse, mutect2, varscan2
- ZNF717 | c.*38C>T | 3'UTR (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
